Somatic mutation profile of tumor specimen TARGET-30-PATVTL-01A (aliquot TARGET-30-PATVTL-01A-01D) from TARGET case TARGET-30-PATVTL, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 2.5 years (931 days).
Specimen TARGET-30-PATVTL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eca5fe50-30ce-4df0-9da2-944f550316be.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATVTL-10A (Blood Derived Normal), aliquot TARGET-30-PATVTL-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3609194f-81c3-4b90-9c9d-18a5c714019b

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Frame Shift Del 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.1039C>T p.Q347* | Nonsense Mutation (SNP) | VAF 66/136 reads (49%) | catalogued as rs1555610910, CS086356, COSV62204363; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.3739_3742del p.F1247Ifs*18 | Frame Shift Del (DEL) | VAF 89/185 reads (48%) | catalogued as rs1064794276; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTPN11 | c.1492C>T p.R498W | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs397507541, CM041072, COSV61005566; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EPHA6 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 67/158 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.716); catalogued as COSV67594400; called by muse, mutect2, varscan2
- DIPK2A | c.1059_1060del p.A354Hfs*30 | Frame Shift Del (DEL) | VAF 48/155 reads (31%) | called by mutect2, pindel, varscan2
